Somatic mutation profile of tumor specimen TCGA-77-7138-01A (aliquot TCGA-77-7138-01A-41D-2042-08) from TCGA case TCGA-77-7138, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.3 years (24,594 days).
Specimen TCGA-77-7138-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07649163-ce26-493e-a792-629cb172ff3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-7138-10A (Blood Derived Normal), aliquot TCGA-77-7138-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60dbc944-3f0d-4b97-b91d-c6cbee2ffc74

The open-access MAF lists 44 somatic variants for this specimen: 35 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 7, Frame Shift Del 2, 3'Flank 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 69/175 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- APOB | c.13363C>T p.L4455F | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.323); catalogued as COSV99265970; called by muse, mutect2
- ATP2B3 | c.3061G>A p.V1021I | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.621); catalogued as rs781795852; called by muse, mutect2, varscan2
- CDC20 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs879241526; called by muse, mutect2
- CDH4 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs572974573, COSV64645801; called by muse, mutect2, varscan2
- COL6A3 | c.3287G>A p.R1096H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs200860322; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FAM234B | c.1190G>A p.C397Y | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.629); catalogued as COSV52194178; called by mutect2, varscan2
- KIF1B | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99822543; called by muse, mutect2, varscan2
- LCT | c.5285A>T p.D1762V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929155; called by muse, mutect2, varscan2
- MLPH | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as rs544688545; called by muse, mutect2, varscan2
- PAPPA2 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV100866460; called by muse, mutect2
- SCN2A | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51856882; called by muse, mutect2
- SPTBN4 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs146428235, COSV58949341; called by muse, mutect2, varscan2
- TP53 | c.818del p.R273Lfs*72 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; called by mutect2, pindel, varscan2
- UNC93B1 | c.667A>G p.I223V | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs377418903; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AAK1 | c.2746G>T p.D916Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ABCA4 | c.2921C>G p.S974C | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C22orf23 | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- DEF8 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); called by muse, mutect2
- EML2 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- GABRB3 | c.1156G>T p.G386C | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- HEATR5A | c.1371del p.I458Ffs*10 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- HERC2 | c.7879C>A p.L2627I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- KCTD6 | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- LILRB2 | c.1054C>T p.H352Y | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- NFASC | c.407T>A p.V136E (on ENST00000339876 / NM_001378329.1; = p.V130E on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); called by muse, mutect2
- NOA1 | c.1196G>A p.R399K | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCNX3 | c.443A>C p.E148A | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.355); called by muse, mutect2
- PLEKHG4B | c.1493G>C p.R498T (on ENST00000283426; = p.R854T on NM_052909.5) | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, varscan2
- SPACA7 | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.076); called by muse, mutect2
- SPEF2 | c.4894C>G p.L1632V | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TAOK2 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TET1 | c.1853T>A p.I618N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USP54 | c.3314C>A p.S1105* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- XKRX | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.187); called by muse, mutect2
- ARHGEF18 | c.3234C>T p.S1078= (on ENST00000359920 / NM_001130955.2; = p.S974= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as rs546637101; called by muse, mutect2, varscan2
- DIP2C | c.3117C>T p.D1039= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as rs772285836; called by muse, mutect2, varscan2
- GABARAP | c.228G>A p.L76= | Silent (SNP) | VAF 59/305 reads (19%) | called by muse, mutect2, varscan2
- HEATR6 | c.2445C>T p.C815= | Silent (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- HLF | c.21G>T p.P7= | Silent (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- INTS5 | c.3054G>T p.G1018= | Silent (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- KIF4B | c.2061C>G p.L687= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as COSV70527503; called by muse, mutect2
- EMC3-AS1 | chr3:10007351 G>C | 3'Flank (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- KIR3DX1 | n.1016G>A | RNA (SNP) | VAF 11/40 reads (28%) | catalogued as rs780169301; called by muse, mutect2, varscan2
